Somatic mutation profile of tumor specimen TCGA-DK-A6AW-01A (aliquot TCGA-DK-A6AW-01A-11D-A30E-08) from TCGA case TCGA-DK-A6AW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 70.2 years (25,644 days).
Specimen TCGA-DK-A6AW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a5525e3-fcc1-48fe-9a25-7024b5032219.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A6AW-10A (Blood Derived Normal), aliquot TCGA-DK-A6AW-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3eba6e6a-edc7-4daf-9a96-f4a9bbc8aefe

The open-access MAF lists 4,296 somatic variants for this specimen: 3,353 protein-altering or splice-affecting, 831 silent, 112 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,849, Silent 831, Nonsense Mutation 421, Splice Site 44, RNA 42, Intron 38, Splice Region 21, Frame Shift Ins 11, 5'Flank 9, 3'UTR 9, 3'Flank 8, 5'UTR 6.

Variants (750 of 4,296; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.2869C>T p.R957* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as rs121918440, CM981521, COSV55934187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACE | c.1486C>T p.R496* | Nonsense Mutation (SNP) | VAF 89/200 reads (45%) | catalogued as rs397514688, CM120946, COSV99326200; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANOS1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 35/35 reads (100%) | catalogued as rs137852516, CM021282, COSV52920162; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANXA11 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs142083484; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 102/107 reads (95%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.9454C>T p.R3152* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as rs587783292, CM142031, COSV54124029; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 46/81 reads (57%) | hotspot (GDC flag); catalogued as rs772821016, CM030188, CS991299, COSV53725394; ClinVar: pathogenic; called by muse, mutect2
- BMPR1A | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as rs587782400, CM014516, COSV64404910; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.6385G>T p.E2129* | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | catalogued as rs886040653, COSV66449661; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.1942G>T p.E648* | Nonsense Mutation (SNP) | VAF 36/81 reads (44%) | catalogued as rs971882211, CM141595, COSV55735390; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL4A3 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1014839148, COSV67414376, COSV67418480; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 37/81 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- GABRA1 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs796052492, COSV50099369, COSV50100120; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs17221854, CM002334, CM142066; ClinVar: pathogenic / not provided / risk factor / likely pathogenic; called by muse, mutect2, varscan2
- MCCC2 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as rs780011606, CM062852, COSV100039738; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH2 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756953958, CM145481, COSV55438798; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.663G>A p.W221* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as rs1555608737, CM143465, COSV62192763; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCNT | c.3880G>T p.E1294* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as rs1359618876, COSV100854950; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 19/38 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- SAMD9 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as rs1186536794, COSV66076161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN9A | c.4378T>G p.F1460V (on ENST00000303354; = p.F1449V on NM_002977.3) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs80356478, CM052913, COSV57625590; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN9A | c.1979C>T p.T660M (on ENST00000303354; = p.T649M on NM_002977.3) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs200965749, COSV57620767; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, varscan2
- TTN | c.70546C>T p.R23516* (on ENST00000591111; = p.R16092* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 51/85 reads (60%) | catalogued as rs1553603394, COSV59899993; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.10612C>T p.R3538* | Nonsense Mutation (SNP) | VAF 39/76 reads (51%) | catalogued as rs878853413, CM159124, COSV56359453; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.1201T>G p.L401V | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62932602; called by muse, mutect2, varscan2
- AAGAB | c.175A>C p.N59H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV56018575; called by muse, mutect2, varscan2
- AARS1 | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs995468279, COSV55749733, COSV55750151; called by muse, mutect2, varscan2
- ABCA12 | c.2851G>A p.E951K (on ENST00000272895 / NM_173076.3; = p.E633K on NM_015657.3) | Missense Mutation (SNP) | VAF 68/83 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1353723813, COSV55948964; called by muse, mutect2, varscan2
- ABCA12 | c.1228C>A p.L410I (on ENST00000272895 / NM_173076.3; = p.L92I on NM_015657.3) | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV55954555, COSV55976882; called by muse, mutect2, varscan2
- ABCA13 | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV101329889; called by muse, mutect2, varscan2
- ABCA13 | c.11968T>G p.F3990V | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71295057, COSV99070605; called by muse, mutect2, varscan2
- ABCA13 | c.13691C>T p.S4564L | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as rs752049932, COSV68946353; called by muse, mutect2, varscan2
- ABCA5 | c.1966C>A p.L656I | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as COSV67019220; called by muse, mutect2, varscan2
- ABCA6 | c.4174G>A p.A1392T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.129); catalogued as rs771167668, COSV52641500; called by muse, mutect2
- ABCA8 | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV52212929; called by muse, mutect2, varscan2
- ABCA8 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52201379; called by muse, varscan2
- ABCA8 | c.11G>T p.R4I | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52212964; called by muse, varscan2
- ABCA9 | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV60631570; called by muse, mutect2, varscan2
- ABCB1 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201352027, COSV55949474; called by muse, mutect2, varscan2
- ABCB11 | c.2843G>A p.R948H | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766286901, COSV55593188, COSV55602049; called by muse, mutect2, varscan2
- ABCB4 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55933378; called by muse, mutect2, varscan2
- ABCB5 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 59/132 reads (45%) | catalogued as COSV51714014; called by muse, mutect2, varscan2
- ABCB5 | c.894G>T p.M298I | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51714800; called by muse, mutect2, varscan2
- ABCB5 | c.1704G>T p.E568D (on ENST00000404938 / NM_001163941.2; = p.E123D on NM_178559.6) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV51721380; called by muse, mutect2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABCB5 | c.2656A>G p.T886A (on ENST00000404938 / NM_001163941.2; = p.T441A on NM_178559.6) | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV51721421; called by muse, mutect2, varscan2
- ABCB8 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); catalogued as COSV52510803; called by muse, mutect2, varscan2
- ABCC11 | c.3287G>A p.R1096Q | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs779688737, COSV62322423; called by muse, mutect2, varscan2
- ABCC2 | c.4237G>T p.A1413S | Missense Mutation (SNP) | VAF 97/236 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.124); catalogued as COSV64988687; called by muse, mutect2, varscan2
- ABCC8 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs765626111, COSV56856749; called by muse, mutect2, varscan2
- ABCC9 | c.4452G>T p.E1484D | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.76); PolyPhen benign (0.039); catalogued as COSV53987441; called by muse, mutect2, varscan2
- ABCE1 | c.1247T>G p.I416S | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56849160; called by muse, mutect2, varscan2
- ABCG1 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs772323233, COSV59205287; called by muse, mutect2, varscan2
- ABCG2 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs780975480, COSV52945734; called by muse, mutect2, varscan2
- ABCG2 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52949818; called by muse, mutect2, varscan2
- ABHD10 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56326456; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1426T>G p.F476V | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as COSV68344678; called by muse, mutect2, varscan2
- ABHD17B | c.223A>C p.K75Q | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV61009304; called by muse, mutect2, varscan2
- ABI1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61020410; called by muse, mutect2, varscan2
- AC013489.1 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs746776924, COSV51550361; called by muse, mutect2, varscan2
- AC023055.1 | c.1360A>G p.N454D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV100278382; called by muse, mutect2, varscan2
- AC104389.6 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as rs33963857, COSV100400543, COSV57963060; called by muse, mutect2, varscan2
- AC131160.1 | c.983A>C p.K328T | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV57702502; called by muse, mutect2, varscan2
- ACAT2 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769205319, COSV58460504; called by muse, mutect2, varscan2
- ACBD3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1278923333, COSV64729525; called by muse, mutect2, varscan2
- ACBD5 | c.406G>T p.E136* (on ENST00000375888 / NM_001352568.1; = p.E138* on NM_145698.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV101022443; called by muse, mutect2, varscan2
- ACOT11 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs150203501; called by muse, mutect2, varscan2
- ACP3 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 25/77 reads (32%) | catalogued as COSV100313051; called by muse, mutect2, varscan2
- ACSF2 | c.540A>C p.Q180H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV51974341; called by muse, mutect2, varscan2
- ACSM1 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as rs376177196; called by muse, mutect2, varscan2
- ACSM2A | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs557161839, COSV54590220; called by muse, mutect2, varscan2
- ACSM2B | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369392849; called by muse, mutect2, varscan2
- ACSM5 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs772542022, COSV59375219; called by muse, mutect2, varscan2
- ACTG2 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.246); catalogued as COSV61828283; called by muse, mutect2, varscan2
- ACTL6A | c.1136A>C p.K379T | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52024109; called by muse, mutect2, varscan2
- ACTN3 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 37/75 reads (49%) | catalogued as rs1208449597, COSV72207551; called by muse, mutect2, varscan2
- ACTN3 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232811519, COSV72207678; called by muse, mutect2, varscan2
- ACTRT2 | c.652A>C p.K218Q | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV65760618; called by muse, mutect2, varscan2
- ACVR1 | c.446T>G p.F149C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55123137; called by muse, mutect2, varscan2
- ADAD1 | c.1694T>C p.I565T | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV56647564; called by muse, mutect2, varscan2
- ADAL | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.632); catalogued as COSV67501491; called by muse, mutect2, varscan2
- ADAM2 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs746785098, COSV55864450; called by muse, mutect2, varscan2
- ADAM23 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 69/79 reads (87%) | catalogued as COSV52209973; called by muse, mutect2, varscan2
- ADAM29 | c.1190T>C p.V397A | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV63668707; called by muse, mutect2, varscan2
- ADAM30 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as rs1325470850, COSV65562370; called by muse, mutect2, varscan2
- ADAM32 | c.1251C>A p.S417R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.149); catalogued as COSV65953875; called by muse, mutect2, varscan2
- ADAMTS18 | c.1134G>T p.K378N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV51423451; called by muse, mutect2, varscan2
- ADAMTS19 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50733429, COSV50802169; called by muse, mutect2, varscan2
- ADAMTS20 | c.3365G>A p.R1122H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as rs752110033, COSV67131309; called by muse, mutect2, varscan2
- ADAMTS20 | c.679G>T p.V227L | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV67140098; called by muse, varscan2
- ADAMTS20 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV67140102; called by muse, varscan2
- ADAMTS3 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 144/312 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV54403760; called by muse, mutect2, varscan2
- ADAMTS8 | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57298060; called by muse, mutect2, varscan2
- ADCY10 | c.1967T>G p.F656C | Missense Mutation (SNP) | VAF 123/250 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63245175; called by muse, mutect2, varscan2
- ADCY10 | c.1667C>T p.T556I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63239335; called by muse, mutect2, varscan2
- ADCY10 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780855146, COSV63239657, COSV63240595; called by muse, mutect2, varscan2
- ADCY10 | c.666dup p.N223Qfs*3 | Frame Shift Ins (INS) | VAF 62/186 reads (33%) | catalogued as rs35604923; called by mutect2, pindel, varscan2
- ADCY2 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs866772904, COSV57902322; called by muse, mutect2, varscan2
- ADCY3 | c.2603T>G p.F868C | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53173130; called by muse, varscan2
- ADCY5 | c.2771T>G p.F924C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV59204877; called by muse, mutect2, varscan2
- ADCY8 | c.1478T>G p.I493S | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53929368; called by muse, mutect2, varscan2
- ADCY9 | c.2218G>T p.D740Y | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53582142; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.825G>A p.G275= | Splice Region (SNP) | VAF 60/157 reads (38%) | catalogued as rs776667228, COSV58445262; called by muse, mutect2, varscan2
- ADD2 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.943); catalogued as COSV52454691; called by muse, mutect2, varscan2
- ADGRA3 | c.3236C>A p.S1079Y | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV51568735, COSV99293145; called by muse, mutect2, varscan2
- ADGRD1 | c.2608G>A p.D870N | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs143670024; called by muse, mutect2, varscan2
- ADGRE2 | c.824G>A p.S275N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100215598; called by muse, mutect2, varscan2
- ADGRF4 | c.81G>T p.K27N | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV51957874, COSV51958580; called by muse, mutect2, varscan2
- ADGRF5 | c.3935G>T p.R1312I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as rs1474274677, COSV99344660; called by muse, mutect2, varscan2
- ADGRG1 | c.302T>G p.L101* | Nonsense Mutation (SNP) | VAF 55/113 reads (49%) | catalogued as COSV101113296; called by muse, mutect2, varscan2
- ADGRV1 | c.1999G>T p.D667Y | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV67995971; called by muse, mutect2, varscan2
- ADGRV1 | c.3147G>T p.E1049D | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV67994486, COSV67995975; called by muse, mutect2, varscan2
- ADGRV1 | c.3752G>T p.R1251I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV67991801; called by muse, mutect2, varscan2
- ADH1C | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs774092660, COSV72463676; called by muse, mutect2, varscan2
- ADORA2A | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 29/50 reads (58%) | catalogued as COSV100417778; called by muse, mutect2, varscan2
- AFF2 | c.2691-1G>T p.X897_splice | Splice Site (SNP) | VAF 11/15 reads (73%) | catalogued as COSV99661330; called by muse, mutect2, varscan2
- AFF3 | c.2625G>T p.M875I | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV57874725; called by muse, mutect2, varscan2
- AFM | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV56922345; called by muse, mutect2, varscan2
- AGBL1 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV66873947; called by muse, mutect2, varscan2
- AGBL2 | c.445C>A p.L149I | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV54095741; called by muse, mutect2, varscan2
- AGBL5 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs781286009, COSV64080852; called by muse, mutect2, varscan2
- AGL | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.801); catalogued as rs759535258, COSV54050692; called by muse, mutect2, varscan2
- AGL | c.4576C>A p.L1526I | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV54059209; called by muse, mutect2, varscan2
- AGPAT3 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52374214; called by muse, mutect2, varscan2
- AGR2 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV101290796, COSV68597127; called by muse, mutect2
- AGR3 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100124073, COSV60037880; called by muse, varscan2
- AGTR2 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV64156612, COSV64157044; called by muse, mutect2, varscan2
- AGXT2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200627716; called by muse, mutect2
- AHCTF1 | c.2062T>G p.L688V (on ENST00000366508; = p.L662V on NM_015446.5) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV58256118; called by muse, mutect2, varscan2
- AHNAK2 | c.14350C>A p.L4784I | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV100317522, COSV60931888; called by muse, mutect2, varscan2
- AHNAK2 | c.7957T>C p.F2653L | Missense Mutation (SNP) | VAF 188/451 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV60931904; called by muse, mutect2, varscan2
- AHRR | c.460A>C p.N154H | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57093956; called by muse, mutect2, varscan2
- AHSG | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56609514, COSV56609686; called by muse, mutect2, varscan2
- AK1 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV56345739; called by muse, mutect2, varscan2
- AK5 | c.246T>G p.N82K (on ENST00000354567 / NM_174858.3; = p.N56K on NM_012093.4) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as COSV58357185; called by muse, mutect2, varscan2
- AK5 | c.493G>T p.E165* (on ENST00000354567 / NM_174858.3; = p.E139* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | catalogued as COSV100481295; called by muse, mutect2, varscan2
- AK5 | c.712G>A p.D238N (on ENST00000354567 / NM_174858.3; = p.D212N on NM_012093.4) | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1019747082, COSV60982163; called by muse, mutect2, varscan2
- AK9 | c.5669C>A p.A1890D | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV69853505; called by muse, mutect2, varscan2
- AK9 | c.3415C>T p.R1139C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs751690548, COSV58151420; called by muse, mutect2, varscan2
- AKAP1 | c.998G>T p.R333I | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV58473162; called by muse, mutect2, varscan2
- AKAP12 | c.1339T>G p.L447V | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV53582643; called by muse, mutect2, varscan2
- AKAP13 | c.3164A>G p.D1055G | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV63470655; called by muse, mutect2, varscan2
- AKAP3 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1187371918, COSV57421039; called by muse, mutect2, varscan2
- AKAP6 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 133/275 reads (48%) | catalogued as COSV55210790, COSV99797455; called by muse, mutect2, varscan2
- AKAP6 | c.6257C>A p.S2086* | Nonsense Mutation (SNP) | VAF 38/72 reads (53%) | catalogued as COSV99797457; called by muse, mutect2, varscan2
- AKAP9 | c.10713C>A p.F3571L (on ENST00000359028; = p.F3547L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.04); catalogued as rs528888059, COSV62358677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKIRIN2 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 34/66 reads (52%) | catalogued as COSV57636251, COSV57637151; called by muse, mutect2, varscan2
- AKR1B15 | c.341G>T p.R114I | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV71152843; called by muse, mutect2, varscan2
- AKR1C2 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.003); catalogued as rs370211227; called by muse, mutect2, varscan2
- AKTIP | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs528168629, COSV50874135; called by muse, mutect2, varscan2
- AL592490.1 | c.2675C>T p.A892V | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV69428002; called by muse, mutect2, varscan2
- ALDH2 | c.491A>C p.D164A | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV55671920; called by muse, mutect2, varscan2
- ALDH3B1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs376028917; called by muse, mutect2, varscan2
- ALG10B | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.02); catalogued as COSV58145053; called by muse, mutect2, varscan2
- ALOX15B | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV66480201; called by muse, mutect2, varscan2
- ALOXE3 | c.509A>C p.K170T | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs1393672475, COSV59078094; called by muse, mutect2, varscan2
- ALPK2 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs142749418; called by muse, mutect2, varscan2
- ALPK2 | c.806A>C p.Y269S | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV64497521; called by muse, mutect2, varscan2
- ALPP | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs778841965, COSV67396862; called by muse, mutect2, varscan2
- AMDHD1 | c.1187C>A p.S396* | Nonsense Mutation (SNP) | VAF 69/168 reads (41%) | catalogued as COSV99900156; called by muse, mutect2, varscan2
- AMER3 | c.2399C>T p.A800V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100365875; called by muse, mutect2, varscan2
- AMPD2 | c.1709T>G p.F570C | Missense Mutation (SNP) | VAF 93/185 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56651022; called by muse, mutect2, varscan2
- AMY2B | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 180/407 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1279658605, COSV63717177; called by muse, mutect2, varscan2
- ANAPC1 | c.2393A>C p.K798T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs756261861, COSV61979746; called by muse, mutect2, varscan2
- ANAPC1 | c.1703A>G p.D568G | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as COSV61979756; called by muse, mutect2, varscan2
- ANAPC1 | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV61979760; called by muse, mutect2, varscan2
- ANAPC5 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 83/170 reads (49%) | catalogued as COSV99945881; called by muse, mutect2, varscan2
- ANGPTL1 | c.665A>C p.H222P | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.044); catalogued as COSV52368297; called by muse, mutect2, varscan2
- ANGPTL5 | c.185A>G p.E62G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV57534686; called by muse, mutect2, varscan2
- ANK2 | c.3577C>T p.R1193C | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148287474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.5356A>G p.K1786E | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); catalogued as COSV52190397; called by muse, mutect2, varscan2
- ANK2 | c.6082C>T p.R2028W | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1411026310, COSV52150851; called by muse, mutect2, varscan2
- ANK2 | c.8811C>A p.F2937L | Missense Mutation (SNP) | VAF 126/276 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52190443; called by muse, mutect2, varscan2
- ANK3 | c.7786C>T p.R2596C | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55053162; called by muse, mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2, varscan2
- ANKAR | c.4070G>A p.R1357Q | Missense Mutation (SNP) | VAF 70/327 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1376221117, COSV51461865; called by muse, mutect2
- ANKLE2 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs761627940, COSV61709114; called by muse, mutect2, varscan2
- ANKRD13C | c.797A>C p.D266A | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV52035498; called by muse, mutect2, varscan2
- ANKRD17 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs763910615, COSV58221383; called by muse, mutect2, varscan2
- ANKRD34B | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV58613677, COSV58614571; called by muse, mutect2, varscan2
- ANKRD42 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as rs780800417, COSV52615647; called by muse, mutect2, varscan2
- ANKRD50 | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.131); catalogued as COSV72385964; called by muse, mutect2, varscan2
- ANKRD7 | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV54554631; called by muse, mutect2, varscan2
- ANKS1B | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 116/245 reads (47%) | catalogued as COSV61334452; called by muse, mutect2, varscan2
- ANKS1B | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61357670, COSV61377939; called by muse, mutect2, varscan2
- ANKS4B | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs536102146, COSV61140399; called by muse, mutect2, varscan2
- ANO3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs766239304, COSV56793786; called by muse, mutect2, varscan2
- ANO4 | c.2047G>T p.E683* (on ENST00000392977 / NM_001286615.2; = p.E648* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 38/99 reads (38%) | catalogued as COSV100151502; called by muse, mutect2, varscan2
- ANXA1 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 58/141 reads (41%) | catalogued as rs756648223, COSV57411924, COSV57412216; called by muse, mutect2, varscan2
- ANXA1 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs1460117107, COSV57412841; called by muse, mutect2, varscan2
- ANXA10 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as rs939324362, COSV63740553; called by muse, mutect2, varscan2
- AOPEP | c.2446G>A p.E816K (on ENST00000375315 / NM_001193329.1; = p.E717K on NM_032823.5) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as rs1378669394, COSV52999540; called by muse, mutect2
- AOX1 | c.2497C>T p.R833C | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749776412, COSV65981358; called by muse, mutect2, varscan2
- AP3B2 | c.2664C>A p.F888L (on ENST00000261722; = p.F882L on NM_004644.5) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.882); catalogued as COSV55614754; called by muse, mutect2, varscan2
- APC | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs200339830, COSV57385047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.5099C>T p.A1700V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs876660893, COSV57385054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOA5 | c.1066C>A p.H356N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as COSV57065218; called by muse, mutect2, varscan2
- APOB | c.9539A>G p.N3180S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV51954033; called by muse, mutect2, varscan2
- APOLD1 | c.686A>C p.K229T (on ENST00000326765 / NM_001130415.2; = p.K198T on NM_030817.3) | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58734400; called by muse, mutect2, varscan2
- APOOL | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 14/15 reads (93%) | catalogued as rs1387460582, COSV100920783; called by muse, mutect2, varscan2
- APP | c.957C>A p.F319L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as COSV61005348; called by muse, mutect2, varscan2
- APTX | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs142133683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs767949083, COSV61268285; called by muse, mutect2, varscan2
- AQP11 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764929288, COSV57992636; called by muse, mutect2, varscan2
- AQP4 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV67218823, COSV67219535; called by muse, mutect2, varscan2
- ARAP2 | c.3046G>T p.D1016Y | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV58292911; called by muse, mutect2, varscan2
- AREL1 | c.1483T>G p.F495V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62668216; called by muse, mutect2, varscan2
- ARFGEF1 | c.2477T>C p.V826A | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51617528; called by muse, mutect2, varscan2
- ARG1 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV51580808, COSV99256308; called by muse, mutect2, varscan2
- ARHGAP11A | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV64381349; called by muse, mutect2, varscan2
- ARHGAP15 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs759344166, COSV54509110, COSV54514150; called by muse, mutect2, varscan2
- ARHGAP15 | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs750786492, COSV54522824; called by muse, mutect2, varscan2
- ARHGAP15 | c.1099T>C p.F367L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); catalogued as COSV54522832; called by muse, mutect2, varscan2
- ARHGAP18 | c.1975A>C p.K659Q | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63766265; called by muse, mutect2, varscan2
- ARHGAP19 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760723887, COSV57396354; called by muse, mutect2, varscan2
- ARHGAP21 | c.3028C>T p.R1010* | Nonsense Mutation (SNP) | VAF 34/103 reads (33%) | catalogued as COSV57610891; called by muse, varscan2
- ARHGAP21 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64544740; called by muse, mutect2, varscan2
- ARHGAP24 | c.1496G>A p.R499Q (on ENST00000395184 / NM_001025616.3; = p.R406Q on NM_031305.3) | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); catalogued as rs115120658, COSV51994561; called by muse, mutect2, varscan2
- ARHGAP26 | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV50842614; called by muse, mutect2, varscan2
- ARHGAP26 | c.703-2A>C p.X235_splice | Splice Site (SNP) | VAF 21/62 reads (34%) | catalogued as COSV50842617; called by muse, mutect2, varscan2
- ARHGAP28 | c.1604T>G p.I535S (on ENST00000383472 / NM_001366230.1; = p.I376S on NM_001010000.3) | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51634456; called by muse, mutect2, varscan2
- ARHGAP44 | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99309872; called by muse, mutect2, varscan2
- ARHGAP5 | c.2350G>A p.A784T | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.18); catalogued as rs749658149, COSV61539135; called by muse, mutect2, varscan2
- ARHGAP9 | c.1075T>G p.F359V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57367837; called by muse, mutect2, varscan2
- ARHGEF10L | c.2414G>T p.S805I | Missense Mutation (SNP) | VAF 139/317 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs1271679786, COSV51441172; called by muse, mutect2, varscan2
- ARHGEF12 | c.943A>C p.K315Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV63107512; called by muse, mutect2, varscan2
- ARID1A | c.2863G>A p.A955T | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV61389837; called by muse, mutect2, varscan2
- ARID1B | c.3415T>G p.F1139V | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51682342; called by muse, mutect2, varscan2
- ARID3C | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV52409237; called by muse, mutect2, varscan2
- ARID5B | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 48/121 reads (40%) | catalogued as COSV99688806, COSV99690781; called by muse, mutect2, varscan2
- ARL15 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.359); catalogued as rs370435144, COSV72292565; called by muse, mutect2, varscan2
- ARL5B | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV66011722; called by muse, mutect2, varscan2
- ARL6IP5 | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56235801; called by muse, mutect2, varscan2
- ARL9 | c.505A>G p.I169V (on ENST00000640821 / NM_001363794.2; = p.I27V on NM_206919.2) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.059); catalogued as COSV63991579; called by muse, mutect2, varscan2
- ARMC2 | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 90/177 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs757791916, COSV64550311, COSV64551406; called by muse, mutect2, varscan2
- ARMC3 | c.733-1G>T p.X245_splice | Splice Site (SNP) | VAF 16/46 reads (35%) | catalogued as COSV53068179; called by muse, mutect2, varscan2
- ARMC3 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473023972, COSV53059669; called by muse, mutect2, varscan2
- ARMCX1 | c.602T>C p.I201T | Missense Mutation (SNP) | VAF 123/135 reads (91%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV65705606; called by muse, mutect2, varscan2
- ARMH4 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 52/95 reads (55%) | catalogued as COSV99957454; called by muse, mutect2, varscan2
- ARPC4 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 7/10 reads (70%) | catalogued as rs1371262365, COSV99809299; called by muse, mutect2, varscan2
- ARPP21 | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV51807915, COSV51809011; called by muse, mutect2, varscan2
- ARRDC5 | c.730C>T p.R244W (on ENST00000381781; = p.R230W on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as rs548886303, COSV67787986; called by muse, mutect2, varscan2
- ART3 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV61915112, COSV61916203; called by muse, mutect2, varscan2
- ASAP2 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV55627220; called by muse, mutect2, varscan2
- ASB4 | c.61T>G p.F21V | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV57509093; called by muse, mutect2, varscan2
- ASB4 | c.1006A>G p.K336E | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV57945870; called by muse, mutect2, varscan2
- ASIC5 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV73332859; called by muse, mutect2, varscan2
- ASPH | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.209); catalogued as rs758840739, COSV62858475; called by muse, mutect2, varscan2
- ASPM | c.9990G>T p.E3330D | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV54139343; called by muse, mutect2, varscan2
- ASPM | c.8636T>G p.F2879C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54139360; called by muse, varscan2
- ASPM | c.5012C>A p.S1671Y | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as COSV54139369; called by muse, mutect2, varscan2
- ASTN1 | c.3426G>T p.K1142N | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV62507489; called by muse, mutect2, varscan2
- ASXL1 | c.3506C>A p.S1169Y | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs1212204313, COSV60103582, COSV60121036; called by muse, mutect2, varscan2
- ASXL2 | c.780A>C p.Q260H | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.78); catalogued as rs760461713, COSV55468436; called by muse, mutect2, varscan2
- ASXL3 | c.2915T>G p.F972C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52480448; called by muse, mutect2, varscan2
- ASXL3 | c.3334G>A p.A1112T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52480476; called by muse, mutect2, varscan2
- ATAD5 | c.1931T>G p.L644* | Nonsense Mutation (SNP) | VAF 45/86 reads (52%) | catalogued as COSV100429554; called by muse, mutect2, varscan2
- ATF6 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 35/75 reads (47%) | catalogued as rs760001414, COSV63405877; called by muse, mutect2, varscan2
- ATF7IP2 | c.1981A>G p.I661V | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV61095520; called by muse, mutect2, varscan2
- ATG13 | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV56322250; called by muse, mutect2, varscan2
- ATG16L1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 83/94 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs746840032, COSV61465102; called by muse, mutect2, varscan2
- ATG4C | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58608660; called by muse, mutect2, varscan2
- ATG4C | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as rs759584462, COSV58606506; called by muse, mutect2, varscan2
- ATG9A | c.443T>C p.I148T | Missense Mutation (SNP) | VAF 67/73 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV60135525; called by muse, mutect2, varscan2
- ATM | c.1567T>G p.F523V | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.074); catalogued as COSV53777098; called by muse, mutect2, varscan2
- ATM | c.4039T>G p.L1347V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV53777124; called by muse, mutect2, varscan2
- ATM | c.6013C>A p.L2005I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53777148, COSV53781102; called by muse, mutect2, varscan2
- ATP10A | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as rs17854738, COSV100791103, COSV63515206; called by muse, mutect2, varscan2
- ATP10D | c.3062C>A p.S1021Y | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV56713472; called by muse, mutect2, varscan2
- ATP13A1 | c.489C>T p.G163= | Splice Region (SNP) | VAF 13/29 reads (45%) | catalogued as rs376339960; called by muse, mutect2, varscan2
- ATP13A5 | c.1684G>T p.D562Y | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV60875932; called by muse, mutect2, varscan2
- ATP1A1 | c.1811G>A p.G604D | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.679); catalogued as COSV55194441; called by muse, mutect2, varscan2
- ATP1A1 | c.2531T>G p.L844R | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55194453; called by muse, mutect2, varscan2
- ATP1A1 | c.3042C>T p.G1014= | Splice Region (SNP) | VAF 32/80 reads (40%) | catalogued as COSV55190117; called by muse, mutect2, varscan2
- ATP1A3 | c.2607C>A p.F869L (on ENST00000545399 / NM_001256214.2; = p.F856L on NM_152296.5) | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as COSV57491436; called by muse, mutect2, varscan2
- ATP1A3 | c.419C>T p.A140V (on ENST00000545399 / NM_001256214.2; = p.A127V on NM_152296.5) | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV57491446; called by muse, mutect2, varscan2
- ATP1A4 | c.2924C>T p.S975F | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63628707; called by muse, mutect2, varscan2
- ATP1B1 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63180216; called by muse, mutect2, varscan2
- ATP23 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs745657952, COSV55685897, COSV55686396; called by muse, mutect2, varscan2
- ATP23 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV55687374; called by muse, mutect2, varscan2
- ATP2A2 | c.1591A>C p.S531R | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as rs1284143094, COSV58047851; called by muse, mutect2, varscan2
- ATP2B1 | c.3355C>T p.R1119* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | catalogued as COSV53806099; called by muse, mutect2, varscan2
- ATP5F1A | c.1641C>A p.F547L | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56361967; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1481G>T p.R494I | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52353394, COSV52354411; called by muse, mutect2, varscan2
- ATP6V1H | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs771448682, COSV62220588; called by muse, mutect2, varscan2
- ATP8A2 | c.892-1G>T p.X298_splice | Splice Site (SNP) | VAF 28/83 reads (34%) | catalogued as COSV54943474; called by muse, mutect2, varscan2
- ATP8B4 | c.426A>C p.Q142H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV99462952; called by muse, mutect2, varscan2
- ATP9A | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 93/223 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV58763543; called by muse, mutect2, varscan2
- ATR | c.7088G>A p.R2363Q | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs142918229, COSV63385448; called by muse, mutect2, varscan2
- ATR | c.1242A>C p.Q414H | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV63392979; called by muse, mutect2, varscan2
- ATRX | c.3569G>A p.R1190K | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV64872623, COSV64874667; called by muse, mutect2, varscan2
- ATXN2L | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV57379263; called by muse, mutect2, varscan2
- ATXN2L | c.2207C>A p.S736* | Nonsense Mutation (SNP) | VAF 53/123 reads (43%) | catalogued as COSV100293303; called by muse, varscan2
- ATXN3 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61497978; called by muse, mutect2, varscan2
- ATXN7L2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs961396530, COSV60205965; called by muse, mutect2, varscan2
- AURKA | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs779964295, COSV57170369; called by muse, mutect2, varscan2
- AURKC | c.842G>T p.R281I (on ENST00000302804 / NM_001015878.2; = p.R247I on NM_003160.3) | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57139723; called by muse, mutect2, varscan2
- AXDND1 | c.2198G>T p.S733I | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV62648992; called by muse, mutect2, varscan2
- AXIN2 | c.90A>C p.E30D | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61061424; called by muse, mutect2, varscan2
- AZI2 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as COSV99843366; called by muse, mutect2, varscan2
- B3GALT1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as rs866876110, COSV59909329; called by muse, mutect2, varscan2
- B3GAT2 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57775118; called by muse, mutect2, varscan2
- B4GALNT1 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV62041934, COSV62043355; called by muse, mutect2, varscan2
- BAMBI | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs369743386; called by muse, mutect2, varscan2
- BANK1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1428281031, COSV59850255; called by muse, mutect2, varscan2
- BARD1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs587781591, COSV53617837; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BBS12 | c.1937G>T p.R646I | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0.056); catalogued as COSV58563153; called by muse, mutect2, varscan2
- BBS7 | c.1025T>A p.I342N | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV52659752; called by muse, mutect2, varscan2
- BBS9 | c.2554G>A p.E852K (on ENST00000242067 / NM_001348036.1; = p.E812K on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV54188729, COSV99626505; called by muse, mutect2
- BCAN | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.114); catalogued as rs759611993, COSV61259806; called by muse, mutect2, varscan2
- BCHE | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs762988755, CM166612, COSV52255080; called by muse, mutect2
- BCKDHB | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.042); catalogued as rs748693585, COSV57519100; called by muse, mutect2, varscan2
- BCL10 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65353663, COSV65353778; called by muse, mutect2, varscan2
- BCO2 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754125457, COSV63065130; called by muse, mutect2, varscan2
- BCOR | c.2690C>T p.S897L | Missense Mutation (SNP) | VAF 51/54 reads (94%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs147251146, COSV60719459; called by muse, mutect2, varscan2
- BEND2 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs761910556, COSV66216023; called by muse, mutect2, varscan2
- BEND2 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV66217406, COSV66217414; called by muse, mutect2, varscan2
- BEND3 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs782423818, COSV64682073; called by muse, mutect2, varscan2
- BEST3 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748231464, COSV56994383; called by muse, mutect2, varscan2
- BEX1 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 123/138 reads (89%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.793); catalogued as COSV65580789; called by muse, mutect2, varscan2
- BHMT2 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs761971562, COSV54871775; called by muse, mutect2, varscan2
- BIRC6 | c.8585C>T p.S2862L | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs747507337, COSV70206564; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747957305, COSV63247494; called by muse, mutect2, varscan2
- BMP10 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV54897009; called by muse, mutect2, varscan2
- BMP2K | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100621425; called by muse, mutect2, varscan2
- BMP6 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs368529770; called by muse, mutect2, varscan2
- BMPER | c.554A>C p.K185T | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV51832157; called by muse, mutect2, varscan2
- BMS1 | c.1342G>T p.D448Y | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV65735630; called by muse, mutect2, varscan2
- BMT2 | c.1182C>A p.F394L | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); catalogued as COSV51781314; called by muse, mutect2, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 29/56 reads (52%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BNC2 | c.1653A>C p.Q551H | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs763083458, COSV66158071; called by muse, mutect2, varscan2
- BNIP5 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | catalogued as COSV71325271, COSV71325897; called by muse, varscan2
- BPIFB6 | c.1133C>A p.S378Y | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62756772; called by muse, mutect2, varscan2
- BPIFB6 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs774420213, COSV62754115, COSV62754524; called by muse, mutect2, varscan2
- BPTF | c.1661-1G>T p.X554_splice | Splice Site (SNP) | VAF 22/52 reads (42%) | catalogued as COSV58847715; called by muse, mutect2, varscan2
- BPTF | c.4832C>T p.S1611L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs776598623, COSV58847753; called by muse, mutect2, varscan2
- BRCA2 | c.9128A>C p.E3043A | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66462867; called by muse, mutect2, varscan2
- BRD1 | c.1459A>G p.R487G | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53461863; called by muse, mutect2, varscan2
- BRD1 | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV53459755, COSV53461879; called by muse, mutect2, varscan2
- BRD2 | c.1653A>C p.K551N | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV66374618; called by muse, mutect2, varscan2
- BRDT | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 38/88 reads (43%) | catalogued as COSV62863553; called by muse, mutect2, varscan2
- BRDT | c.2038G>T p.D680Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as rs1298671999, COSV62867883; called by muse, mutect2, varscan2
- BRINP1 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.222); catalogued as rs1281945379, COSV56314086; called by muse, mutect2, varscan2
- BRIX1 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745745891, COSV59132201; called by muse, mutect2, varscan2
- BRSK1 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1355958794, COSV58670301; called by muse, mutect2, varscan2
- BSX | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV58006427; called by muse, mutect2, varscan2
- BTBD10 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs369987366; called by muse, mutect2, varscan2
- BTBD3 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV54781837; called by muse, mutect2, varscan2
- BTLA | c.702C>A p.F234L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV57940790; called by muse, mutect2, varscan2
- BTNL9 | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV59793626; called by muse, mutect2, varscan2
- BUD23 | c.499A>C p.N167H | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56096431; called by muse, mutect2, varscan2
- C10orf99 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV64532244; called by muse, mutect2, varscan2
- C11orf24 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58506677; called by muse, mutect2, varscan2
- C11orf80 | c.1468C>A p.R490S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV60929254, COSV60931469; called by muse, mutect2, varscan2
- C12orf4 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as COSV99712495; called by muse, mutect2, varscan2
- C12orf40 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61138068; called by muse, mutect2, varscan2
- C12orf56 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs764750881, COSV61487157; called by muse, mutect2, varscan2
- C14orf39 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 33/59 reads (56%) | catalogued as COSV100407132, COSV58781579; called by muse, mutect2, varscan2
- C15orf39 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1335572690, COSV62295936; called by muse, mutect2, varscan2
- C16orf87 | c.434G>T p.R145I | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53512906; called by muse, mutect2, varscan2
- C16orf87 | c.166A>C p.N56H | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV53512917; called by muse, mutect2, varscan2
- C1QTNF9 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100129765; called by muse, mutect2
- C1QTNF9 | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.216); catalogued as COSV59657939, COSV59658280; called by muse, varscan2
- C1QTNF9B | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV65944641; called by muse, varscan2
- C1QTNF9B | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65944644; called by muse, mutect2, varscan2
- C1orf141 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV63993380, COSV63993425; called by muse, mutect2, varscan2
- C1orf159 | c.406C>T p.R136W (on ENST00000379339 / NM_001330306.2; = p.R100W on NM_017891.5) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs761836332, COSV53882915; called by muse, mutect2, varscan2
- C1orf21 | c.321T>G p.I107M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52413256; called by muse, mutect2, varscan2
- C20orf85 | c.255C>A p.V85= | Splice Region (SNP) | VAF 19/38 reads (50%) | catalogued as COSV64519360, COSV64519964; called by muse, mutect2, varscan2
- C2CD3 | c.1936T>G p.Y646D | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58101569; called by muse, mutect2, varscan2
- C2CD5 | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV61728024; called by muse, mutect2, varscan2
- C2orf16 | c.870C>A p.F290L | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1354200224, COSV68647299; called by muse, mutect2, varscan2
- C2orf16 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV62678510; called by muse, mutect2, varscan2
- C3orf14 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs1559812991, COSV51707702, COSV99223699; called by muse, mutect2, varscan2
- C3orf62 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 49/97 reads (51%) | catalogued as rs755185861, COSV100542893; called by muse, mutect2, varscan2
- C3orf70 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 94/184 reads (51%) | catalogued as COSV100621102; called by muse, mutect2, varscan2
- C4BPA | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.373); catalogued as rs1366967873, COSV65535824, COSV65537022; called by muse, mutect2, varscan2
- C4orf45 | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV71701384; called by muse, mutect2, varscan2
- C5 | c.1510T>G p.L504V | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.284); catalogued as COSV56332362; called by muse, mutect2, varscan2
- C5 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1254646813, COSV56332372, COSV99799073; called by muse, mutect2, varscan2
- C5AR1 | c.84A>C p.K28N | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV61893568; called by muse, mutect2, varscan2
- C5AR1 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61893573; called by muse, mutect2, varscan2
- C5AR1 | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.173); catalogued as COSV61893576; called by muse, mutect2, varscan2
- C8A | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV63486633; called by muse, varscan2
- C8orf34 | c.1420G>T p.G474* | Nonsense Mutation (SNP) | VAF 27/53 reads (51%) | catalogued as COSV100297340; called by muse, mutect2, varscan2
- C8orf34 | c.1481T>C p.V494A | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.028); catalogued as COSV57399831; called by muse, mutect2, varscan2
- C8orf74 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs775912708, COSV58754234; called by muse, mutect2, varscan2
- C9orf24 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as rs1165709635, COSV52624756; called by muse, mutect2, varscan2
- CACNA1D | c.3614C>T p.S1205L (on ENST00000350061 / NM_001128840.3; = p.S1225L on NM_000720.4) | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1183389331, COSV55454582; called by muse, mutect2, varscan2
- CACNA2D1 | c.163A>G p.N55D | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV62393484; called by muse, mutect2, varscan2
- CADPS | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760015455, COSV51900880; called by muse, mutect2, varscan2
- CAGE1 | c.2318G>T p.R773I (on ENST00000512086; = p.R637I on NM_205864.3) | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); catalogued as COSV57076477; called by muse, mutect2, varscan2
- CAGE1 | c.1615G>A p.E539K (on ENST00000512086; = p.E403K on NM_205864.3) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs1482505651, COSV57074979; called by muse, mutect2, varscan2
- CALCOCO1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs376685260, COSV50425439; called by muse, mutect2, varscan2
- CALCR | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs747921380, COSV64012253; called by muse, mutect2, varscan2
- CALD1 | c.1489G>A p.E497K (on ENST00000361675 / NM_033138.4; = p.E242K on NM_004342.7) | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV62654616, COSV62655881; called by muse, mutect2, varscan2
- CAMSAP2 | c.1980T>G p.D660E (on ENST00000236925 / NM_001297707.2; = p.D649E on NM_203459.3) | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52677817; called by muse, mutect2, varscan2
- CAMTA2 | c.2265C>A p.F755L | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV61833253; called by muse, mutect2, varscan2
- CAPN13 | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99699585; called by muse, mutect2, varscan2
- CAPN13 | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV54430154, COSV54430735; called by muse, mutect2, varscan2
- CAPN6 | c.1604A>C p.E535A | Missense Mutation (SNP) | VAF 82/84 reads (98%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as COSV60697406; called by muse, mutect2, varscan2
- CAPN9 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0.183); catalogued as rs750960558, COSV55232886; called by muse, mutect2, varscan2
- CAPSL | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs17851540, COSV68439529; called by muse, mutect2, varscan2
- CAPZA2 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV100753932, COSV63266023; called by muse, mutect2, varscan2
- CAPZA3 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs777052411, COSV56848439; called by muse, mutect2, varscan2
- CARD11 | c.687C>T p.I229= | Splice Region (SNP) | VAF 45/105 reads (43%) | catalogued as rs369930171; called by muse, mutect2, varscan2
- CARF | c.1993C>A p.H665N | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV57550117; called by muse, mutect2, varscan2
- CARNMT1 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV65194572; called by muse, mutect2, varscan2
- CARNMT1 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | catalogued as rs748737629, COSV100961052; called by muse, mutect2, varscan2
- CASD1 | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348103453, COSV51975793; called by muse, mutect2, varscan2
- CASKIN1 | c.1363C>A p.Q455K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV58877343; called by muse, mutect2, varscan2
- CASKIN1 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as rs768787471, COSV100623794, COSV58877369; called by muse, mutect2, varscan2
- CASP5 | c.575G>T p.R192I | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52832006; called by muse, mutect2, varscan2
- CASP8 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51847352, COSV51857450; called by muse, mutect2, varscan2
- CASTOR1 | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV57577180; called by muse, mutect2, varscan2
- CATSPERE | c.800A>G p.K267R | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63682369; called by muse, mutect2, varscan2
- CATSPERE | c.1885A>C p.K629Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV63676682; called by muse, mutect2, varscan2
- CAVIN1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as COSV63812830; called by muse, mutect2, varscan2
- CBLL1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV56030586; called by muse, mutect2, varscan2
- CBY2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs1399175372, COSV60117172; called by muse, mutect2, varscan2
- CCDC102B | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 77/180 reads (43%) | catalogued as COSV100101711; called by muse, mutect2, varscan2
- CCDC113 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1262608912, COSV54688000; called by muse, mutect2, varscan2
- CCDC134 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as rs1326490150, COSV55388573, COSV55388864; called by muse, mutect2, varscan2
- CCDC136 | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV52801920, COSV52805329; called by muse, mutect2, varscan2
- CCDC141 | c.3815T>C p.F1272S | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1301103743, COSV55383029; called by muse, mutect2, varscan2
- CCDC141 | c.2239G>T p.E747* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV99836001, COSV99836610; called by muse, mutect2, varscan2
- CCDC15 | c.2213T>C p.L738S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61085047; called by muse, mutect2, varscan2
- CCDC183 | c.1132A>C p.M378L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61041011; called by muse, mutect2, varscan2
- CCDC190 | c.830T>G p.F277C | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV63363681; called by muse, mutect2, varscan2
- CCDC27 | c.1343A>G p.Q448R | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53903903; called by muse, mutect2, varscan2
- CCDC30 | c.1436C>T p.S479F (on ENST00000340612; = p.S436F on NM_001080850.3) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV59609206, COSV59609619; called by muse, mutect2, varscan2
- CCDC47 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs764969232, COSV56724331, COSV56724963, COSV99854393; called by muse, mutect2, varscan2
- CCDC54 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV53759969; called by muse, mutect2, varscan2
- CCDC60 | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 106/209 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59551051; called by muse, mutect2, varscan2
- CCDC65 | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.136); catalogued as rs764695480, COSV56739759, COSV56740351; called by muse, mutect2, varscan2
- CCDC78 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 69/131 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.308); catalogued as COSV52405026; called by muse, mutect2, varscan2
- CCDC80 | c.1774G>T p.E592* | Nonsense Mutation (SNP) | VAF 77/168 reads (46%) | catalogued as COSV99244113; called by muse, mutect2, varscan2
- CCDC80 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as COSV52818383; called by muse, mutect2, varscan2
- CCDC81 | c.1413A>T p.K471N (on ENST00000445632 / NM_001156474.2; = p.K381N on NM_021827.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV53581900, COSV99564216; called by muse, mutect2, varscan2
- CCDC87 | c.393C>A p.Y131* | Nonsense Mutation (SNP) | VAF 32/101 reads (32%) | catalogued as COSV100039690; called by muse, mutect2, varscan2
- CCDC88A | c.2493G>T p.K831N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV55070640; called by muse, mutect2, varscan2
- CCER1 | c.651G>T p.Q217H | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV62648646; called by muse, mutect2, varscan2
- CCKBR | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.77); PolyPhen benign (0.017); catalogued as COSV58106018; called by muse, mutect2, varscan2
- CCL22 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV54660850; called by muse, mutect2, varscan2
- CCL27 | c.311A>T p.N104I | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52405806; called by muse, mutect2, varscan2
- CCM2L | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs778563139, COSV52950492, COSV99395164; called by muse, mutect2, varscan2
- CCM2L | c.1187C>T p.S396F (on ENST00000452892 / NM_001365692.1; = p.L375F on NM_080625.4) | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs771691411, COSV52949462, COSV52952933; called by muse, mutect2, varscan2
- CCN2 | c.915C>A p.F305L | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63466833, COSV63467053; called by muse, mutect2, varscan2
- CCR5 | c.657A>C p.K219N | Missense Mutation (SNP) | VAF 125/288 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as COSV52753159; called by muse, mutect2, varscan2
- CCR9 | c.871G>A p.V291I (on ENST00000357632 / NM_031200.3; = p.V279I on NM_006641.4) | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs201135152, COSV62940252; called by muse, mutect2, varscan2
- CCSER1 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1414232911, COSV61472294; called by muse, mutect2, varscan2
- CCT6B | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as COSV58488224; called by muse, mutect2, varscan2
- CD1D | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs182855664, COSV63808761; called by muse, mutect2, varscan2
- CD2AP | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV63763222; called by muse, mutect2, varscan2
- CD2AP | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs199622885, COSV63763227; called by muse, mutect2, varscan2
- CD2AP | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.804); catalogued as rs1437681570, COSV63763230; called by muse, mutect2, varscan2
- CD33 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV51800539; called by muse, mutect2, varscan2
- CD36 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs766072001, COSV59217553; called by muse, mutect2, varscan2
- CD3E | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV62346708; called by muse, mutect2, varscan2
- CD3G | c.450G>T p.K150N | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52676333; called by muse, mutect2, varscan2
- CD4 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as rs373415505; called by muse, mutect2, varscan2
- CD5L | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs146902396, COSV63822495; called by muse, mutect2, varscan2
- CD7 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.498); catalogued as rs752636901, COSV53940920; called by muse, mutect2, varscan2
- CDC7 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs375702482, COSV52309241, COSV99319834; called by muse, mutect2, varscan2
- CDCA7 | c.313G>A p.D105N (on ENST00000347703 / NM_145810.3; = p.D184N on NM_031942.5) | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV60721934; called by muse, mutect2, varscan2
- CDCA7L | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs377233838; called by muse, mutect2, varscan2
- CDCA7L | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV62258624; called by muse, mutect2, varscan2
- CDCP1 | c.1109T>G p.F370C | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV56108258; called by muse, mutect2, varscan2
- CDH10 | c.277T>G p.L93V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52598984; called by muse, mutect2, varscan2
- CDH11 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs551918062, COSV51778517; called by muse, mutect2, varscan2
- CDH17 | c.985A>C p.K329Q | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as COSV50342638; called by muse, mutect2, varscan2
- CDH18 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV56951035; called by muse, mutect2, varscan2
- CDH18 | c.1238C>A p.T413N | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.333); catalogued as COSV56963328; called by muse, mutect2, varscan2
- CDH19 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.998); catalogued as rs1450796895, COSV50956040, COSV50959604; called by muse, mutect2, varscan2
- CDH2 | c.1949G>T p.R650I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV52271391, COSV52289630; called by muse, mutect2, varscan2
- CDH5 | c.424C>A p.H142N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as COSV100439023, COSV58520218; called by muse, mutect2, varscan2
- CDH5 | c.1180C>A p.L394M | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.152); catalogued as rs986062102, COSV58520222; called by muse, mutect2, varscan2
- CDH6 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs757234769, COSV54068487; called by muse, mutect2, varscan2
- CDH8 | c.2201A>G p.N734S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV54902713; called by muse, mutect2, varscan2
- CDHR1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs201649854; called by muse, mutect2, varscan2
- CDHR1 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV60566637; called by muse, mutect2, varscan2
- CDHR2 | c.3735C>T p.S1245= | Splice Region (SNP) | VAF 23/59 reads (39%) | catalogued as rs767243776, COSV56145869; called by muse, mutect2, varscan2
- CDK12 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs201479472, COSV71000175, COSV71002573; called by muse, mutect2, varscan2
- CDK13 | c.2770G>T p.E924* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99474834; called by muse, mutect2, varscan2
- CDK2AP2 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs911403058, COSV56874638; called by muse, mutect2, varscan2
- CDK5R2 | c.695C>A p.T232K | Missense Mutation (SNP) | VAF 70/85 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV56936916, COSV56937507; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3322G>T p.E1108* | Nonsense Mutation (SNP) | VAF 41/86 reads (48%) | catalogued as COSV100574969; called by muse, mutect2, varscan2
- CDK6 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV99720562; called by muse, mutect2
- CDK7 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as COSV56515942; called by muse, mutect2, varscan2
- CDRT1 | c.1038T>G p.N346K | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV55414045; called by muse, mutect2, varscan2
- CEACAM1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 112/226 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as rs190497484; called by muse, mutect2, varscan2
- CEACAM8 | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.719); catalogued as COSV54991902; called by muse, varscan2
- CEL | c.605C>T p.A202V (on ENST00000673714; = p.A199V on NM_001807.6) | Missense Mutation (SNP) | VAF 83/354 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs372564944; called by muse, mutect2, varscan2
- CELF4 | c.171C>A p.F57L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58467047; called by muse, mutect2, varscan2
- CELSR1 | c.8179G>A p.A2727T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as rs377639775; called by muse, mutect2, varscan2
- CEMIP | c.1554C>A p.F518L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV54991814; called by muse, mutect2, varscan2
- CEMIP | c.1806C>A p.D602E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55000770; called by muse, mutect2, varscan2
- CENPE | c.7670C>A p.S2557Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.854); catalogued as COSV54391095, COSV99476964; called by muse, varscan2
- CENPE | c.4195A>G p.T1399A | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54391119; called by muse, mutect2, varscan2
- CENPE | c.2464T>G p.F822V | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV54391140; called by muse, mutect2, varscan2
- CENPF | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs763766300, COSV65277043; called by muse, mutect2, varscan2
- CENPF | c.6380G>A p.R2127H | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs776162995, COSV65275853; called by muse, mutect2, varscan2
- CENPN | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 27/50 reads (54%) | catalogued as rs745658924, COSV55141960; called by muse, mutect2, varscan2
- CENPP | c.299A>C p.K100T | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV65042020; called by muse, mutect2
- CEP112 | c.1219-1G>T p.X407_splice | Splice Site (SNP) | VAF 17/39 reads (44%) | catalogued as COSV67144990; called by muse, mutect2, varscan2
- CEP120 | c.1089G>T p.K363N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60268820; called by muse, mutect2, varscan2
- CEP126 | c.3145C>A p.L1049I | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV54831049; called by muse, mutect2, varscan2
- CEP128 | c.1515G>T p.E505D | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV55391589, COSV99823847; called by muse, mutect2, varscan2
- CEP135 | c.2764C>T p.R922* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as rs369943972; called by muse, mutect2, varscan2
- CEP152 | c.1104G>T p.K368N | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV57861628; called by muse, mutect2, varscan2
- CEP162 | c.776A>G p.K259R | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV57624958; called by muse, mutect2, varscan2
- CEP164 | c.2148G>T p.Q716H | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV54046625; called by muse, mutect2, varscan2
- CEP250 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV61174847; called by muse, varscan2
- CEP44 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs769157129, COSV56658367; called by muse, mutect2, varscan2
- CEP55 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV65185988; called by muse, mutect2, varscan2
- CEP83 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 50/121 reads (41%) | catalogued as rs1216945458, COSV60407553; called by muse, mutect2, varscan2
- CEP85 | c.1242G>T p.K414N | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV53327451; called by muse, mutect2, varscan2
- CEP97 | c.562-1G>T p.X188_splice | Splice Site (SNP) | VAF 19/35 reads (54%) | catalogued as COSV59128295; called by muse, mutect2, varscan2
- CEP97 | c.2076G>T p.E692D | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV59123261; called by muse, mutect2, varscan2
- CERS6 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs753478893, COSV59832147; called by muse, mutect2, varscan2
- CES3 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV57595563; called by muse, mutect2, varscan2
- CETN2 | c.500A>C p.K167T | Missense Mutation (SNP) | VAF 54/60 reads (90%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.703); catalogued as COSV64745400; called by muse, mutect2, varscan2
- CFAP100 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV61504495; called by muse, mutect2, varscan2
- CFAP251 | c.3035T>G p.F1012C | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV56616224; called by muse, mutect2, varscan2
- CFAP298 | c.700A>C p.I234L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV51593761; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV55829859; called by muse, mutect2, varscan2
- CFAP43 | c.3365A>G p.D1122G | Missense Mutation (SNP) | VAF 156/364 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63852558; called by muse, mutect2, varscan2
- CFAP45 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV63648087; called by muse, mutect2, varscan2
- CFAP47 | c.1893G>T p.K631N | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs747060647, COSV52882246, COSV52887910; called by muse, mutect2, varscan2
- CFAP52 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 36/78 reads (46%) | catalogued as rs775639416, COSV100234649; called by muse, mutect2, varscan2
- CFAP54 | c.7377+1G>A p.X2459_splice | Splice Site (SNP) | VAF 26/75 reads (35%) | catalogued as COSV61575522; called by muse, mutect2, varscan2
- CFAP54 | c.8176G>T p.G2726* | Nonsense Mutation (SNP) | VAF 34/86 reads (40%) | catalogued as COSV100732854; called by muse, mutect2, varscan2
- CFAP58 | c.1465A>C p.N489H | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV63836573; called by muse, mutect2, varscan2
- CFAP58 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs748990071, COSV100866105, COSV63835126; called by muse, mutect2, varscan2
- CFAP65 | c.1908C>A p.F636L | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV58562000; called by muse, mutect2, varscan2
- CFAP69 | c.419C>A p.S140* | Nonsense Mutation (SNP) | VAF 38/104 reads (37%) | catalogued as COSV100289674; called by muse, mutect2, varscan2
- CFAP69 | c.2296G>T p.E766* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as rs1335664641, COSV60185689, COSV60187937; called by muse, mutect2, varscan2
- CFAP70 | c.1854+1G>A p.X618_splice | Splice Site (SNP) | VAF 25/57 reads (44%) | catalogued as COSV60287104; called by muse, mutect2, varscan2
- CFAP70 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.787); catalogued as COSV60287108; called by muse, mutect2, varscan2
- CFAP74 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.091); catalogued as rs746490453, COSV54564801; called by muse, mutect2, varscan2
- CFAP92 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | catalogued as COSV54049093, COSV99414509; called by muse, varscan2
- CFAP92 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV54049053; called by muse, mutect2, varscan2
- CFAP97 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57112244; called by muse, mutect2, varscan2
- CFH | c.68A>C p.E23A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.439); catalogued as COSV62778894; called by muse, mutect2, varscan2
- CFHR4 | c.191G>A p.G64E (on ENST00000367416 / NM_001201551.2; = p.G65E on NM_006684.5) | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.807); catalogued as COSV52236032; called by muse, mutect2, varscan2
- CFHR5 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.383); catalogued as rs534950713, COSV56826328, COSV56829144; called by muse, mutect2, varscan2
- CFI | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 138/312 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV67100039; called by muse, mutect2, varscan2
- CFTR | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs761884881, COSV50109940; called by muse, mutect2, varscan2
- CGA | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 52/134 reads (39%) | catalogued as COSV100851643; called by muse, mutect2, varscan2
- CGB8 | c.11T>G p.F4C | Missense Mutation (SNP) | VAF 117/287 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as COSV56823252, COSV56823873; called by muse, mutect2, varscan2
- CGNL1 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.068); catalogued as rs149796026; called by muse, mutect2, varscan2
- CGRRF1 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV53596389; called by muse, mutect2, varscan2
- CGRRF1 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV53598301; called by muse, mutect2, varscan2
- CHAC2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs768976504, COSV54858130; called by muse, mutect2, varscan2
- CHD1 | c.3160C>T p.R1054* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99398953; called by muse, mutect2, varscan2
- CHD1 | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52344989; called by muse, mutect2, varscan2
- CHD4 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 99/210 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs760698915, COSV58911225; called by muse, mutect2, varscan2
- CHD5 | c.4739A>T p.D1580V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.103); catalogued as COSV52425799; called by muse, mutect2, varscan2
- CHD6 | c.7084C>A p.L2362I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64694791; called by muse, mutect2, varscan2
- CHD9 | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); catalogued as COSV68300477; called by muse, mutect2, varscan2
- CHD9 | c.1816A>C p.K606Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV101271829; called by muse, mutect2, varscan2
- CHD9 | c.4157G>A p.R1386H | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1422237630, COSV54617032; called by muse, mutect2, varscan2
- CHGB | c.1320C>A p.F440L | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV66761842; called by muse, mutect2, varscan2
- CHGB | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1252421481, COSV66761847; called by muse, mutect2, varscan2
- CHL1 | c.2081G>A p.R694K (on ENST00000397491 / NM_001253387.1; = p.R710K on NM_006614.4) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as rs1374020812, COSV56607323; called by muse, mutect2, varscan2
- CHL1 | c.3175T>C p.F1059L (on ENST00000397491 / NM_001253387.1; = p.F1075L on NM_006614.4) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV56607335; called by muse, mutect2, varscan2
- CHP2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs756478431, COSV55649342; called by muse, mutect2, varscan2
- CHRM2 | c.543T>A p.F181L | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57785313; called by muse, mutect2, varscan2
- CHRM5 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 101/232 reads (44%) | catalogued as rs763280962, COSV67248076; called by muse, mutect2, varscan2
- CHRNA1 | c.777C>A p.F259L (on ENST00000261007 / NM_001039523.3; = p.F234L on NM_000079.4) | Missense Mutation (SNP) | VAF 76/147 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV53685426; called by muse, mutect2, varscan2
- CHRNA4 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as rs1247664860, COSV64719141; called by muse, mutect2, varscan2
- CHRNA5 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV55140789; called by muse, mutect2, varscan2
- CHRNB1 | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53441376; called by muse, mutect2, varscan2
- CHST1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV57324761, COSV57325892; called by muse, mutect2, varscan2
- CHST15 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1417205522, COSV60566027; called by muse, mutect2, varscan2
- CHSY3 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV59289094; called by muse, mutect2, varscan2
- CHUK | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64918800; called by muse, mutect2, varscan2
- CIB3 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.517); catalogued as COSV54167774; called by muse, mutect2, varscan2
- CILP | c.2182A>G p.T728A | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.626); catalogued as COSV56028157; called by muse, mutect2, varscan2
- CIT | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs781056753, COSV55859602; called by muse, mutect2, varscan2
- CKAP5 | c.5867G>A p.R1956Q (on ENST00000529230 / NM_001008938.4; = p.R1896Q on NM_014756.3) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as rs1164209175, COSV56367440; called by muse, mutect2, varscan2
- CKB | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1380864359, COSV62379730; called by muse, mutect2, varscan2
- CLASP1 | c.2851T>G p.L951V | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55341770; called by muse, mutect2
- CLASP2 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs754123905, COSV56288167; called by muse, mutect2, varscan2
- CLCA1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs753995315, COSV52324938, COSV52328286; called by muse, mutect2, varscan2
- CLCA1 | c.2389C>A p.L797I | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV52331640; called by muse, mutect2, varscan2
- CLCA1 | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV52331651; called by muse, mutect2, varscan2
- CLCA4 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 95/179 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144781260, COSV55371380; called by muse, mutect2, varscan2
- CLCN1 | c.1554G>T p.K518N | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.588); catalogued as COSV58374737; called by muse, mutect2, varscan2
- CLCNKB | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as CD075351, COSV65161924; called by muse, mutect2, varscan2
- CLDN10 | c.173C>A p.S58Y | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs1232436168, COSV65300045; called by muse, mutect2, varscan2
- CLDN2 | c.469A>C p.K157Q | Missense Mutation (SNP) | VAF 71/79 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61021354; called by muse, mutect2, varscan2
- CLDN25 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 64/129 reads (50%) | catalogued as rs754824119, COSV71620427, COSV71620465; called by muse, mutect2, varscan2
- CLDN5 | c.352G>A p.A118T (on ENST00000618236 / NM_001363066.2; = p.A203T on NM_003277.4) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.098); catalogued as COSV54248882; called by muse, mutect2, varscan2
- CLEC4D | c.302A>C p.D101A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV55230986; called by muse, mutect2, varscan2
- CLEC4E | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55224981; called by muse, mutect2, varscan2
- CLIC2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1326420135, COSV58936128; called by muse, mutect2, varscan2
- CLIP4 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100191280, COSV60750701; called by muse, mutect2, varscan2
- CLK4 | c.1338G>T p.E446D | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV60321280; called by muse, mutect2, varscan2
- CLMN | c.2351C>T p.S784L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs35569227; called by muse, mutect2, varscan2
- CLN3 | c.956G>A p.R319H (on ENST00000360019 / NM_001286104.2; = p.R343H on NM_000086.2) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as rs771305783, COSV61107913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLNK | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1455938088, COSV57014686, COSV99904403; called by muse, varscan2
- CLNK | c.809G>T p.R270I | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57015239, COSV99904405; called by muse, varscan2
- CLSPN | c.2035G>T p.E679* | Nonsense Mutation (SNP) | VAF 24/40 reads (60%) | catalogued as COSV52047060, COSV99230119; called by muse, mutect2, varscan2
- CLSTN1 | c.1213C>A p.L405I (on ENST00000377298 / NM_001009566.3; = p.L395I on NM_014944.4) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs909340223, COSV63651306; called by muse, mutect2, varscan2
- CLTC | c.3019C>A p.L1007M | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52253441; called by muse, mutect2, varscan2
- CLVS1 | c.233G>T p.R78I | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100370844, COSV57983669; called by muse, mutect2, varscan2
- CMYA5 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 82/193 reads (42%) | catalogued as COSV101483724; called by muse, mutect2, varscan2
- CMYA5 | c.3547G>T p.E1183* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as rs1166057346, COSV101483725; called by muse, mutect2, varscan2
- CMYA5 | c.7079C>A p.S2360Y | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV71409742; called by muse, mutect2, varscan2
- CNBD2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs539557197, COSV62588051; called by muse, mutect2, varscan2
- CNDP1 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as COSV62593825; called by muse, mutect2, varscan2
- CNDP2 | c.649T>G p.F217V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.372); catalogued as COSV60841759; called by muse, mutect2, varscan2
- CNGA2 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 58/61 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61703584, COSV61706403; called by muse, mutect2, varscan2
- CNGA3 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs370911601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNKSR2 | c.308T>C p.I103T | Missense Mutation (SNP) | VAF 68/77 reads (88%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.574); catalogued as COSV54267279; called by muse, mutect2, varscan2
- CNOT1 | c.4547G>A p.G1516D | Missense Mutation (SNP) | VAF 109/258 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.558); catalogued as COSV55322684; called by muse, mutect2, varscan2
- CNOT1 | c.3340A>C p.K1114Q | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1174995907, COSV55322693; called by muse, mutect2, varscan2
- CNOT1 | c.3192A>C p.K1064N | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV55322710; called by muse, mutect2, varscan2
- CNOT10 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV59393115, COSV59395529; called by muse, mutect2, varscan2
- CNTLN | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV52068057; called by muse, mutect2, varscan2
- CNTN2 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59353292; called by muse, mutect2, varscan2
- CNTNAP2 | c.1241A>G p.H414R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV62263539; called by muse, mutect2, varscan2
- CNTNAP2 | c.1526G>T p.S509I | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV62263541; called by muse, mutect2, varscan2
- CNTNAP4 | c.3200C>A p.S1067Y | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271815, COSV56671209; called by muse, mutect2, varscan2
- CNTNAP5 | c.1158T>G p.I386M | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV70513527; called by muse, varscan2
- CNTNAP5 | c.1229C>A p.S410Y | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV70513530; called by muse, varscan2
- CNTNAP5 | c.2515C>T p.R839* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV70474923; called by muse, mutect2, varscan2
- CNTNAP5 | c.3701G>A p.R1234Q | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs201560627, COSV70484932; called by muse, mutect2, varscan2
- COBL | c.2060C>A p.S687* | Nonsense Mutation (SNP) | VAF 36/95 reads (38%) | catalogued as COSV99470927; called by muse, mutect2, varscan2
- COCH | c.638G>A p.R213Q (on ENST00000216361 / NM_001347720.1; = p.R148Q on NM_004086.3) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs543399762, COSV53551657; called by muse, mutect2, varscan2
- COL11A1 | c.5292A>C p.E1764D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV62198908; called by muse, mutect2, varscan2
- COL11A1 | c.544T>C p.C182R | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62198922; called by muse, mutect2, varscan2
- COL11A2 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs575597368, COSV59502994; called by muse, mutect2, varscan2
- COL12A1 | c.4746G>T p.M1582I | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV59408864; called by muse, mutect2, varscan2
- COL14A1 | c.3724G>T p.D1242Y | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as COSV52863853, COSV52869803; called by muse, mutect2, varscan2
- COL15A1 | c.2686A>G p.K896E | Missense Mutation (SNP) | VAF 99/246 reads (40%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.994); catalogued as COSV66649635; called by muse, mutect2, varscan2
- COL19A1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV59589556; called by muse, mutect2, varscan2
- COL24A1 | c.2756G>A p.S919N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1206523669, COSV65314785; called by muse, mutect2, varscan2
- COL28A1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs200904642, COSV68084986; called by muse, mutect2, varscan2
- COL3A1 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs863223362, COSV58591872; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV66415720; called by muse, mutect2, varscan2
- COL5A3 | c.4343G>A p.G1448D | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53419855; called by muse, mutect2, varscan2
- COL6A2 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100152809, COSV56004151; called by muse, mutect2, varscan2
- COL6A2 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56016759; called by muse, mutect2, varscan2
- COL6A3 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs763810209, COSV55088249; called by muse, mutect2, varscan2
- COL7A1 | c.8642A>G p.D2881G | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV56477335; called by muse, mutect2, varscan2
- COL8A2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs748713100, COSV100290885; called by muse, varscan2
- COLGALT2 | c.1293G>T p.K431N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV62300777; called by muse, mutect2, varscan2
- COPB1 | c.2398T>G p.F800V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51451026; called by muse, mutect2, varscan2
- COPS2 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM137474, COSV54645795, COSV54646335; called by muse, mutect2, varscan2
- COPS2 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV54646035; called by muse, mutect2, varscan2
- CORIN | c.1165A>C p.N389H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV56699997; called by muse, mutect2, varscan2
- COX7A2 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 91/188 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as rs371766385, COSV57874336; called by muse, mutect2, varscan2
- CPA3 | c.443C>A p.T148N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56047260; called by muse, mutect2, varscan2
- CPA6 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775233588, COSV52721227; called by muse, mutect2, varscan2
- CPA6 | c.696C>A p.F232L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV52743487; called by muse, mutect2, varscan2
- CPAMD8 | c.1702C>T p.R568C (on ENST00000651564; = p.R521C on NM_015692.5) | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs762584662, COSV52230795; called by muse, mutect2
- CPAMD8 | c.824A>C p.K275T (on ENST00000651564; = p.K228T on NM_015692.5) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV99358846; called by muse, mutect2
- CPD | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | catalogued as COSV56716204; called by muse, mutect2, varscan2
- CPE | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68579224; called by muse, mutect2, varscan2
- CPEB1 | c.1744C>T p.P582S (on ENST00000617958; = p.P517S on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs893878284, COSV55617331; called by muse, mutect2, varscan2
- CPED1 | c.1519A>C p.N507H | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV60013754; called by muse, mutect2, varscan2
- CPNE2 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs748574324, COSV51960798; called by muse, mutect2, varscan2
- CPNE4 | c.828T>G p.N276K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.059); catalogued as COSV70200460; called by muse, mutect2, varscan2
- CPNE9 | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV56068061, COSV56068362; called by muse, mutect2
- CPSF2 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 60/117 reads (51%) | catalogued as COSV54098319; called by muse, mutect2, varscan2
- CPSF3 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.276); catalogued as COSV53012138; called by muse, mutect2, varscan2
- CPXCR1 | c.128A>C p.Q43P | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52162524, COSV52164617; called by muse, mutect2, varscan2
- CR2 | c.326G>T p.R109I | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV65509753; called by muse, mutect2, varscan2
- CR2 | c.2612C>A p.S871Y | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.828); catalogued as COSV65509758; called by muse, mutect2, varscan2
- CRB1 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs140214293; called by muse, mutect2, varscan2
- CRB1 | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.637); catalogued as COSV66334114; called by muse, mutect2, varscan2
- CREBBP | c.4174C>T p.R1392* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as CM085348, COSV52122363; called by muse, mutect2, varscan2
- CREBBP | c.2168C>A p.S723* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as COSV99268203; called by muse, mutect2, varscan2
- CRISPLD1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51543751; called by muse, mutect2, varscan2
- CRMP1 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61483259; called by muse, mutect2, varscan2
- CRYBB1 | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV53234840; called by muse, mutect2, varscan2
- CSE1L | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as COSV99521762, COSV99521765; called by muse, mutect2, varscan2
- CSE1L | c.1976T>G p.F659C | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53703203; called by muse, mutect2, varscan2
- CSK | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328560214, COSV54976235; called by muse, mutect2, varscan2
- CSMD1 | c.7426C>T p.R2476* (on ENST00000520002; = p.R2475* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as COSV59278640, COSV59306178; called by muse, mutect2, varscan2
- CSMD3 | c.7108C>A p.L2370I (on ENST00000297405 / NM_001363185.1; = p.L2266I on NM_052900.3) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs764284781, COSV52148172, COSV52173782; called by muse, mutect2, varscan2
- CSMD3 | c.6692G>A p.R2231Q (on ENST00000297405 / NM_001363185.1; = p.R2127Q on NM_052900.3) | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.6); catalogued as rs751658267, COSV52145865, COSV99832218; called by muse, mutect2, varscan2
- CSMD3 | c.6577A>G p.T2193A (on ENST00000297405 / NM_001363185.1; = p.T2089A on NM_052900.3) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52328805; called by muse, mutect2, varscan2
- CSMD3 | c.5659G>A p.G1887R (on ENST00000297405 / NM_001363185.1; = p.G1783R on NM_052900.3) | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs149542393; called by muse, mutect2, varscan2
- CSMD3 | c.3637C>T p.R1213* (on ENST00000297405 / NM_001363185.1; = p.R1109* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 40/109 reads (37%) | catalogued as rs780503678, COSV52288397, COSV99830283; called by muse, mutect2, varscan2
- CSMD3 | c.2962G>A p.D988N (on ENST00000297405 / NM_001363185.1; = p.D884N on NM_052900.3) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52328852; called by muse, varscan2
- CSMD3 | c.1901G>T p.S634I (on ENST00000297405 / NM_001363185.1; = p.S530I on NM_052900.3) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV52328871; called by muse, mutect2, varscan2
- CSMD3 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.65); catalogued as COSV52228252; called by muse, mutect2, varscan2
- CSN1S1 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 57/124 reads (46%) | catalogued as COSV99886420; called by muse, mutect2, varscan2
- CSNK2A1 | c.337T>G p.F113V | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV53937864; called by muse, mutect2, varscan2
- CSPG4 | c.3925T>G p.S1309A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV100413217; called by muse, mutect2, varscan2
- CSRNP3 | c.1228C>A p.L410I | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV58776611, COSV58786192; called by muse, varscan2
- CTAGE1 | c.1727T>G p.F576C | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV66945104; called by muse, varscan2
- CTAGE6 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 14/101 reads (14%) | catalogued as COSV101417794, COSV99070150; called by mutect2, varscan2
- CTCF | c.1891G>T p.E631* | Nonsense Mutation (SNP) | VAF 92/228 reads (40%) | catalogued as COSV50462752; called by muse, mutect2, varscan2
- CTNNA2 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); catalogued as rs1278915845, COSV63564488; called by muse, mutect2, varscan2
- CTNNA2 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.25); catalogued as rs754689563, COSV58167333; called by muse, mutect2, varscan2
- CTNNA2 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773814879, COSV58183464; called by muse, mutect2, varscan2
- CTNNA2 | c.2208A>C p.K736N | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58183482; called by muse, mutect2, varscan2
- CTNNA3 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 41/94 reads (44%) | catalogued as COSV100373163; called by muse, mutect2, varscan2
- CTNND2 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs143679932, COSV58913975; called by muse, mutect2, varscan2
- CTPS1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs376715076; called by muse, mutect2, varscan2
- CTSC | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs768506957, COSV57060566; called by muse, mutect2, varscan2
- CTSK | c.158dup p.N53Kfs*9 | Frame Shift Ins (INS) | VAF 12/33 reads (36%) | catalogued as rs764168526; called by mutect2, varscan2
- CTSO | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 44/111 reads (40%) | catalogued as rs559355629, COSV70810048; called by muse, mutect2, varscan2
- CTSV | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV52345880; called by muse, mutect2, varscan2
- CTXN3 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as rs773647759, COSV65218898; called by muse, mutect2, varscan2
- CUBN | c.4838G>A p.R1613Q | Missense Mutation (SNP) | VAF 104/233 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs147343635, COSV64727922; called by muse, mutect2, varscan2
- CUBN | c.191G>T p.R64I | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV64702058; called by muse, mutect2, varscan2
- CUL3 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV52370988; called by muse, mutect2, varscan2
- CUL7 | c.4607C>T p.S1536L | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs765173994, CM090878, COSV54820653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUTA | c.331G>A p.G111R (on ENST00000488034 / NM_001014840.2; = p.G88R on NM_015921.3) | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53386926, COSV99538801; called by muse, mutect2, varscan2
- CUX1 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); catalogued as COSV52917014; called by muse, mutect2, varscan2
- CWF19L2 | c.2599G>T p.E867* | Nonsense Mutation (SNP) | VAF 39/87 reads (45%) | catalogued as COSV99978030; called by muse, mutect2, varscan2
- CXADR | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99514919; called by muse, mutect2, varscan2
- CXCR3 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.793); catalogued as rs1240827614, COSV65462384; called by muse, mutect2, varscan2
- CYLC1 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61409762; called by muse, mutect2, varscan2
- CYLD | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61097562; called by muse, mutect2, varscan2
- CYP21A2 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV64489396; called by muse, mutect2, varscan2
- CYP2B6 | c.1274C>A p.A425D | Missense Mutation (SNP) | VAF 131/277 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs768260761, COSV57845637; called by muse, mutect2, varscan2
- CYP2C8 | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV64879068; called by muse, mutect2, varscan2
- CYP3A4 | c.222T>G p.F74L | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60504418; called by muse, mutect2, varscan2
- CYP46A1 | c.283-1G>T p.X95_splice | Splice Site (SNP) | VAF 175/383 reads (46%) | catalogued as COSV55896799; called by muse, mutect2, varscan2
- CYP46A1 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55896808; called by muse, mutect2, varscan2
- CYP4A11 | c.635+2T>G p.X212_splice | Splice Site (SNP) | VAF 28/88 reads (32%) | catalogued as COSV60225850; called by muse, mutect2, varscan2
- CYP4B1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as rs139750942; called by muse, mutect2, varscan2
- CYP4F11 | c.827G>A p.C276Y | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs760692119, COSV56129731; called by muse, mutect2, varscan2
- CYP4F8 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV57854406; called by muse, mutect2, varscan2
- CYP4V2 | c.1040C>A p.S347Y | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.492); catalogued as COSV66507564; called by muse, mutect2, varscan2
- CYP7A1 | c.708G>T p.E236D | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as COSV56963428, COSV56965989; called by muse, varscan2
- CYP7A1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749230759, COSV56962076; called by muse, varscan2
- CYRIA | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as rs776202730, COSV62866091; called by muse, mutect2, varscan2
- CYRIA | c.299-1G>T p.X100_splice | Splice Site (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100838278, COSV62867355; called by muse, mutect2, varscan2
- DAB1 | c.838G>T p.E280* (on ENST00000371231; = p.E247* on NM_021080.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 77/182 reads (42%) | catalogued as COSV100976115; called by muse, mutect2, varscan2
- DACH1 | c.1484C>T p.A495V (on ENST00000619232 / NM_001366712.1; = p.A443V on NM_080759.6) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.074); catalogued as rs1222609467, COSV57520736; called by muse, mutect2, varscan2
- DAGLB | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs574498107, COSV51704262; called by muse, mutect2, varscan2
- DAPK1 | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 95/213 reads (45%) | catalogued as COSV100800726; called by muse, mutect2, varscan2
- DAPP1 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56449701; called by muse, mutect2, varscan2
- DARS2 | c.1846_1862del p.N616Pfs*3 | Frame Shift Del (DEL) | VAF 33/83 reads (40%) | catalogued as COSV53409331; called by mutect2, pindel, varscan2
- DCAF1 | c.3848G>A p.R1283Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60046385; called by muse, mutect2, varscan2
- DCAF10 | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54287205, COSV99647540; called by muse, mutect2, varscan2
- DCAF12 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as rs372624056, COSV100778433; called by muse, mutect2, varscan2
- DCAF13 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs978385936, COSV52574120; called by muse, mutect2, varscan2
- DCAF17 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100265966; called by muse, mutect2, varscan2
- DCAF4L2 | c.1176C>A p.F392L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV100150390; called by muse, mutect2
- DCAF8L1 | c.1650C>A p.F550L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV71595542; called by muse, mutect2, varscan2
- DCANP1 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs577312184, COSV72345820; called by muse, mutect2, varscan2
3,546 further variants in this file (2,603 protein-altering or splice-affecting, 831 silent, 112 other) are not listed here.
